Somatic mutation profile of tumor specimen 0DKWND from CCDI case PBBYNW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 21.1 years (7,695 days).
Specimen 0DKWND: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69a52a6e-8afd-4e81-89ec-0c0b4340d931.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKWNP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e671c6b-f325-40d2-967e-b2d2483cd7e0

The open-access MAF lists 65 somatic variants for this specimen: 40 protein-altering or splice-affecting, 11 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 11, Frame Shift Del 7, Intron 6, Nonsense Mutation 4, 3'UTR 4, Frame Shift Ins 3, 5'UTR 3, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAAF4 | c.523dup p.I175Nfs*15 | Frame Shift Ins (INS) | VAF 608/1634 reads (37%) | catalogued as rs751610886; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ALPK1 | c.784C>T p.Q262* | Nonsense Mutation (SNP) | VAF 481/1534 reads (31%) | catalogued as COSV99455065; called by muse, mutect2, varscan2
- CRYBG3 | c.1024G>T p.E342* | Nonsense Mutation (SNP) | VAF 658/1715 reads (38%) | catalogued as rs1265618618; called by muse, mutect2, varscan2
- CTNNB1 | c.1466A>G p.Y489C | Missense Mutation (SNP) | VAF 628/990 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as rs780428505; called by muse, mutect2, varscan2
- EPPK1 | c.2650C>T p.R884W | Missense Mutation (SNP) | VAF 181/434 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs782397509; called by muse, mutect2, varscan2
- FAT3 | c.12764G>A p.G4255E | Missense Mutation (SNP) | VAF 289/792 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.067); catalogued as COSV99972422; called by mutect2, varscan2
- GNLY | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 344/966 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs755303248; called by muse, mutect2, varscan2
- MAST1 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 247/699 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367682332; called by muse, mutect2, varscan2
- OR5T1 | c.344T>C p.L115P | Missense Mutation (SNP) | VAF 582/1504 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57301554; called by muse, mutect2, varscan2
- PCDH9 | c.1675A>G p.I559V | Missense Mutation (SNP) | VAF 32/1028 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.166); catalogued as rs1238489844; called by muse, mutect2
- SETD2 | c.4582G>C p.E1528Q | Missense Mutation (SNP) | VAF 364/566 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100338473, COSV57452009; called by muse, mutect2, varscan2
- TAF1 | c.3004C>T p.R1002C (on ENST00000373790 / NM_138923.4; = p.R1023C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 852/1089 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52114997, COSV52118430; called by muse, mutect2, varscan2
- TRAPPC11 | c.1719del p.S574Afs*6 | Frame Shift Del (DEL) | VAF 618/1955 reads (32%) | catalogued as rs763507812; called by mutect2, pindel, varscan2
- TUBA3C | c.1145C>T p.T382M | Missense Mutation (SNP) | VAF 483/1322 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs200139610; called by muse, mutect2, varscan2
- AC008676.3 | c.529G>T p.G177W | Missense Mutation (SNP) | VAF 196/500 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- AC008676.3 | c.528G>T p.Q176H | Missense Mutation (SNP) | VAF 196/512 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- ADAM10 | c.1664G>A p.C555Y | Missense Mutation (SNP) | VAF 682/1122 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD36C | c.125A>C p.Y42S | Missense Mutation (SNP) | VAF 574/1452 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C12orf56 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 325/787 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- C9orf135 | c.470C>A p.S157* | Nonsense Mutation (SNP) | VAF 598/1772 reads (34%) | called by mutect2, varscan2
- CALR3 | c.4del p.A2Pfs*27 | Frame Shift Del (DEL) | VAF 115/408 reads (28%) | called by mutect2, pindel, varscan2
- CCAR1 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 253/703 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDC5L | c.1992_2002del p.Y665Ffs*16 | Frame Shift Del (DEL) | VAF 510/1606 reads (32%) | called by mutect2, pindel, varscan2
- DIO3 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 265/686 reads (39%) | called by muse, mutect2, varscan2
- DPH5 | c.406dup p.W136Lfs*12 | Frame Shift Ins (INS) | VAF 532/1095 reads (49%) | called by mutect2, pindel, varscan2
- ERBB4 | c.2064A>T p.R688S | Missense Mutation (SNP) | VAF 688/1824 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- HMGXB3 | c.3407C>A p.A1136D (on ENST00000613459; = p.A890D on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 388/1241 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- KHDRBS2 | c.149_156del p.L50Hfs*46 | Frame Shift Del (DEL) | VAF 602/2130 reads (28%) | called by mutect2, pindel*, varscan2*
- LGMN | c.1103C>G p.S368C | Missense Mutation (SNP) | VAF 308/860 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- LILRB5 | c.1699G>T p.A567S (on ENST00000449561 / NM_001081442.3; = p.A566S on NM_006840.5) | Missense Mutation (SNP) | VAF 452/1437 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2
- MAST1 | c.540del p.H180Qfs*53 | Frame Shift Del (DEL) | VAF 315/888 reads (35%) | called by mutect2, pindel, varscan2
- MCM3AP | c.1756G>T p.G586W | Missense Mutation (SNP) | VAF 423/1187 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by mutect2, varscan2
- MYO3A | c.2341_2345delinsG p.Q781Gfs*24 | Frame Shift Del (DEL) | VAF 380/1510 reads (25%) | called by pindel, varscan2*
- NPHP1 | c.943A>G p.N315D (on ENST00000393272 / NM_207181.4; = p.N316D on NM_000272.5) | Missense Mutation (SNP) | VAF 599/1642 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PDGFRA | c.1025A>G p.Y342C | Missense Mutation (SNP) | VAF 7818/9714 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- PKD1L3 | c.1496T>A p.L499H | Missense Mutation (SNP) | VAF 595/1748 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PRPF31 | c.197dup p.I67Dfs*2 | Frame Shift Ins (INS) | VAF 307/1006 reads (31%) | called by mutect2, pindel, varscan2
- SLCO4A1 | c.1843_1844del p.L615Gfs*8 | Frame Shift Del (DEL) | VAF 240/878 reads (27%) | called by mutect2, pindel, varscan2
- TNFRSF10D | c.150+1G>T p.X50_splice | Splice Site (SNP) | VAF 421/1151 reads (37%) | called by muse, mutect2, varscan2
- UPB1 | c.293G>A p.R98K | Missense Mutation (SNP) | VAF 570/1370 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASXL3 | c.2388C>T p.N796= | Silent (SNP) | VAF 667/1853 reads (36%) | catalogued as rs1468383989; called by muse, mutect2, varscan2
- ERCC2 | c.672A>G p.E224= | Silent (SNP) | VAF 382/1033 reads (37%) | called by muse, mutect2, varscan2
- FAM83G | c.2394C>A p.A798= | Silent (SNP) | VAF 335/965 reads (35%) | called by muse, mutect2, varscan2
- ITGAM | c.1587G>A p.G529= (on ENST00000648685 / NM_001145808.2; = p.G528= on NM_000632.4) | Silent (SNP) | VAF 498/1256 reads (40%) | catalogued as rs756150459, COSV54936670; called by muse, mutect2, varscan2
- NUP188 | c.3996C>T p.F1332= | Silent (SNP) | VAF 49/1280 reads (4%) | called by muse, mutect2
- OR56A3 | c.123G>A p.L41= | Silent (SNP) | VAF 539/804 reads (67%) | catalogued as COSV61570301; called by muse, mutect2, varscan2
- PLA2R1 | c.330C>G p.L110= | Silent (SNP) | VAF 352/1205 reads (29%) | catalogued as rs147284017, COSV51778970; called by muse, mutect2, varscan2
- PLCD3 | c.456G>C p.L152= | Silent (SNP) | VAF 293/639 reads (46%) | called by muse, mutect2, varscan2
- SRFBP1 | c.612A>G p.P204= | Silent (SNP) | VAF 965/2671 reads (36%) | catalogued as rs1002697856, COSV100232880; called by muse, mutect2, varscan2
- TECPR1 | c.1392C>G p.A464= | Silent (SNP) | VAF 161/436 reads (37%) | catalogued as COSV101130514; called by muse, mutect2, varscan2
- TFCP2 | c.843C>T p.P281= | Silent (SNP) | VAF 651/1865 reads (35%) | catalogued as rs140688280; called by muse, mutect2, varscan2
- ABI3BP | c.1577-12067T>C | Intron (SNP) | VAF 581/1505 reads (39%) | called by muse, mutect2, varscan2
- CMC1 | c.-3G>A | 5'UTR (SNP) | VAF 228/361 reads (63%) | called by muse, mutect2, varscan2
- F12 | c.1251-55C>T | Intron (SNP) | VAF 33/464 reads (7%) | called by muse, mutect2
- GMDS | c.*47_*48del | 3'UTR (DEL) | VAF 171/568 reads (30%) | catalogued as rs761385469; called by pindel, varscan2
- GOT2 | c.597+27G>A | Intron (SNP) | VAF 411/1082 reads (38%) | catalogued as rs1170346752; called by muse, mutect2, varscan2
- KAT6B | c.3372+33G>A | Intron (SNP) | VAF 203/487 reads (42%) | catalogued as rs748336787; called by muse, varscan2
- KLK14 | c.-32del | 5'UTR (DEL) | VAF 304/1060 reads (29%) | called by mutect2, pindel, varscan2
- PCOLCE2 | c.*76dup | 3'UTR (INS) | VAF 200/494 reads (40%) | catalogued as rs918444729; called by mutect2, varscan2
- PCYOX1L | c.470+20G>C | Intron (SNP) | VAF 408/972 reads (42%) | called by muse, mutect2, varscan2
- PKIB | c.*51G>A | 3'UTR (SNP) | VAF 489/800 reads (61%) | called by muse, mutect2, varscan2
- PLAAT2 | c.*80G>T | 3'UTR (SNP) | VAF 128/446 reads (29%) | called by muse, mutect2, varscan2
- SRPK2 | chr7:105389354 C>T | 5'Flank (SNP) | VAF 435/1136 reads (38%) | called by muse, mutect2, varscan2
- SUSD4 | c.725-5648G>T | Intron (SNP) | VAF 610/1570 reads (39%) | catalogued as COSV59553368; called by muse, mutect2, varscan2
- TYSND1 | c.-101_-66del | 5'UTR (DEL) | VAF 41/133 reads (31%) | called by mutect2, pindel
